Somatic mutation profile of tumor specimen MP2PRT-PANWXD-TMP1-A (aliquot MP2PRT-PANWXD-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANWXD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,156 days).
Specimen MP2PRT-PANWXD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02ed1cd9-7993-4b3b-8b13-870b471273ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANWXD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANWXD-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1de4c020-0aab-4612-8de8-7b91572341ad

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.12592C>T p.R4198* | Nonsense Mutation (SNP) | VAF 66/560 reads (12%) | catalogued as rs587783685, CM122102, COSV56409006, COSV56429446; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL11A2 | c.4933G>A p.V1645I (on ENST00000341947 / NM_080680.3; = p.V1538I on NM_080679.2) | Missense Mutation (SNP) | VAF 30/1004 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs556677734, COSV59493876; called by muse, mutect2
- RASGRP2 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 66/707 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV62449205; called by muse, mutect2
- IGHV3-43 | chr14:106470256 CACTGTGTA>GCAAGG | Missense Mutation (DEL) | VAF 14/103 reads (14%) | called by pindel, varscan2*
- HIVEP2 | c.6705G>A p.Q2235= | Silent (SNP) | VAF 104/463 reads (22%) | called by muse, mutect2, varscan2
